Somatic mutation profile of tumor specimen TCGA-AO-A0JB-01A (aliquot TCGA-AO-A0JB-01A-11W-A071-09) from TCGA case TCGA-AO-A0JB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.8 years (18,561 days).
Specimen TCGA-AO-A0JB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5e25393-43a2-4641-a2f0-21d5e8e7b20d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0JB-10A (Blood Derived Normal), aliquot TCGA-AO-A0JB-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6a02832-ac78-41c3-b204-9a252ac6445c

The open-access MAF lists 98 somatic variants for this specimen: 77 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 19, Frame Shift Del 6, Nonsense Mutation 4, Splice Site 3, Intron 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 30/52 reads (58%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG2 | c.1040C>T p.S347F (on ENST00000379869 / NM_001079858.3; = p.S344F on NM_005756.4) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.439); catalogued as rs1249561200, COSV61341643; called by muse, mutect2, varscan2
- AP3B2 | c.3181G>A p.G1061R (on ENST00000261722; = p.G1055R on NM_004644.5) | Missense Mutation (SNP) | VAF 34/327 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV99916982; called by muse, mutect2, varscan2
- ATP13A3 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 15/386 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV99757613; called by muse, mutect2
- ATP13A3 | c.52-1G>A p.X18_splice | Splice Site (SNP) | VAF 15/233 reads (6%) | catalogued as COSV99757396, COSV99757617; called by muse, mutect2
- B3GNT9 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.153); catalogued as COSV54629596; called by muse, mutect2, varscan2
- BTN3A3 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV55074007; called by muse, mutect2, varscan2
- C2CD3 | c.4964C>T p.T1655I | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV100487371; called by muse, mutect2
- C2orf16 | c.3677C>A p.A1226D | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV62678676; called by muse, mutect2, varscan2
- CDCA5 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99298024; called by muse, mutect2
- CDH19 | c.120A>C p.R40S | Missense Mutation (SNP) | VAF 82/126 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50980011; called by muse, mutect2, varscan2
- CEP68 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV53125104; called by muse, mutect2, varscan2
- COL4A1 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV65432708; called by muse, mutect2, varscan2
- CRYBG1 | c.5511T>G p.S1837R | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.898); catalogued as COSV100954612; called by muse, mutect2
- CSMD3 | c.1996G>T p.D666Y (on ENST00000297405 / NM_001363185.1; = p.D562Y on NM_052900.3) | Missense Mutation (SNP) | VAF 90/395 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52093321, COSV52334796; called by muse, mutect2, varscan2
- CUEDC1 | c.281G>T p.S94I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV64227365; called by muse, mutect2, varscan2
- DENND1B | c.1623A>C p.E541D | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as COSV54159437; called by muse, mutect2, varscan2
- DNAJB8 | c.340T>G p.F114V | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV59879697; called by muse, mutect2, varscan2
- DST | c.16303C>T p.Q5435* (on ENST00000361203 / NM_001374722.1; = p.Q3023* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 81/337 reads (24%) | catalogued as COSV55043222; called by muse, mutect2, varscan2
- EPB41L4B | c.2582C>T p.S861F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV65805271; called by muse, varscan2
- ERMARD | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV64651722; called by muse, mutect2, varscan2
- FGD2 | c.1644C>A p.C548* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV99236616; called by muse, mutect2
- FGD2 | c.1645A>G p.S549G | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99236621; called by muse, mutect2
- FLG | c.1291A>G p.N431D | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs765082230, COSV64244295; called by muse, varscan2
- GCM2 | c.133T>G p.Y45D | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65276714; called by muse, mutect2, varscan2
- GLB1L3 | c.422T>G p.L141R | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV66283682; called by muse, mutect2, varscan2
- HEATR1 | c.5662G>A p.E1888K | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as COSV100857791; called by muse, mutect2
- HERC4 | c.2964G>T p.L988= (on ENST00000395198 / NM_022079.3; = p.L980= on NM_015601.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 24/68 reads (35%) | catalogued as COSV53275828; called by muse, mutect2, varscan2
- HOXD3 | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs140883088, COSV50885898; called by muse, mutect2, varscan2
- HTR1B | c.380del p.S127Cfs*43 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as COSV100885493, COSV64052020; called by mutect2, pindel, varscan2
- ISLR2 | c.1183T>G p.S395A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV100679766; called by muse, mutect2
- KCNIP4 | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54844919; called by muse, mutect2, varscan2
- KCNK5 | c.329C>G p.A110G | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV63989518; called by muse, mutect2, varscan2
- KLKB1 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763038724, COSV99250401; called by muse, mutect2
- LCE1F | c.283T>C p.C95R | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57670366; called by muse, varscan2
- LHX9 | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 25/679 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.77); catalogued as COSV100436069; called by muse, mutect2
- LIPN | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.545); catalogued as rs567792606, COSV68383905; called by muse, mutect2, varscan2
- LOXL3 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV51215714; called by muse, mutect2, varscan2
- LPO | c.1447C>G p.Q483E | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV51858885, COSV51863032; called by muse, mutect2, varscan2
- LTBP1 | c.3898G>A p.A1300T (on ENST00000404816 / NM_206943.4; = p.A974T on NM_000627.4) | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99698760; called by muse, mutect2
- MGA | c.4824T>A p.N1608K | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV54964191; called by muse, mutect2, varscan2
- PAQR9 | c.1066C>A p.L356M | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100503920, COSV61418752; called by muse, mutect2
- PRRC2B | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV61943758; called by muse, mutect2, varscan2
- PZP | c.3774G>T p.Q1258H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54371440; called by muse, mutect2, varscan2
- RAB9B | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs1321964920, COSV54588235; called by muse, mutect2, varscan2
- RTL9 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 177/478 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71826514; called by muse, mutect2, varscan2
- SCN3A | c.4619T>G p.M1540R | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV51826112; called by muse, mutect2, varscan2
- SEMG1 | c.953C>A p.T318N | Missense Mutation (SNP) | VAF 104/151 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV54874844; called by muse, mutect2, varscan2
- SERPINA4 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.069); catalogued as rs748691639, COSV54071830; called by muse, mutect2, varscan2
- SERPINF1 | c.451A>C p.K151Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV54618073; called by mutect2, varscan2
- SIK2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1306786104, COSV59256388; called by muse, mutect2, varscan2
- SPTA1 | c.380A>G p.E127G | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV63760542; called by muse, mutect2, varscan2
- SRRM4 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs200755711; called by muse, mutect2, varscan2
- TBX22 | c.649A>G p.M217V | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV64788119; called by muse, mutect2, varscan2
- TLR4 | c.1586A>G p.H529R (on ENST00000355622 / NM_138554.5; = p.H489R on NM_003266.4) | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV62924417; called by muse, mutect2, varscan2
- TRAM1L1 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.158); catalogued as COSV60293542; called by muse, mutect2, varscan2
- TUBB4B | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.09); catalogued as COSV61119165; called by muse, mutect2, varscan2
- TYW3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1347091799, COSV100904907, COSV63803198; called by muse, mutect2
- UBR1 | c.1353G>T p.E451D | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV51937181; called by muse, mutect2, varscan2
- UCP2 | c.94T>A p.F32I | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.643); catalogued as COSV60105372; called by muse, mutect2, varscan2
- USH2A | c.12680A>G p.D4227G | Missense Mutation (SNP) | VAF 112/405 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV56446688; called by muse, mutect2, varscan2
- USP2 | c.1710G>A p.W570* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99489958; called by muse, mutect2
- ZNF319 | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV54624189; called by muse, mutect2, varscan2
- ZNF407 | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV55272099; called by muse, mutect2, varscan2
- ZNF439 | c.39G>T p.E13D | Missense Mutation (SNP) | VAF 27/338 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as rs747151122, COSV100397569; called by muse, mutect2
- ZNF582 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 45/489 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100018942; called by muse, mutect2
- ZNF671 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100235239; called by muse, mutect2
- ZNF671 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV58054648; called by muse, varscan2
- ANKRD20A1 | c.2295_2296del p.G767Lfs*3 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- ANKRD20A2P | c.2295_2296del p.G767Lfs*3 | Frame Shift Del (DEL) | VAF 31/154 reads (20%) | called by mutect2, pindel, varscan2
- ANKS4B | c.284_313del p.D95_A104del | In Frame Del (DEL) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- PDE4DIP | c.240C>A p.N80K | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- PIP4K2C | c.794_813+4del p.X265_splice | Splice Site (DEL) | VAF 29/121 reads (24%) | called by mutect2, pindel, varscan2
- SH3KBP1 | c.772_799del p.S258Rfs*8 | Frame Shift Del (DEL) | VAF 42/252 reads (17%) | called by mutect2, pindel
- THOC5 | c.1594-2A>G p.X532_splice | Splice Site (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2
- TTN | c.96645_96679del p.D32215Efs*4 (on ENST00000591111; = p.D24791Efs*4 on NM_003319.4) | Frame Shift Del (DEL) | VAF 109/188 reads (58%) | called by mutect2, pindel, varscan2
- VPS50 | c.1909_1912del p.H637Sfs*35 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel, varscan2
- AGO1 | c.1176C>T p.I392= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as rs1296302699, COSV100940922; called by muse, mutect2
- ATAD2 | c.2832T>G p.P944= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV54887425; called by muse, mutect2, varscan2
- COL6A3 | c.3501C>T p.I1167= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as rs199998363, COSV55112672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD2 | c.8910C>T p.Y2970= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV99594930; called by muse, mutect2
- DBR1 | c.336G>T p.V112= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV53431328; called by muse, mutect2, varscan2
- FAM135A | c.441C>A p.G147= (on ENST00000370479 / NM_001351599.1; = p.G104= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV52060287; called by muse, mutect2, varscan2
- FAT4 | c.2379C>T p.F793= | Silent (SNP) | VAF 4/95 reads (4%) | catalogued as COSV101272734; called by muse, mutect2
- FRRS1 | c.1446T>C p.H482= | Silent (SNP) | VAF 58/149 reads (39%) | catalogued as rs148375757; called by muse, mutect2, varscan2
- GPAT2 | c.1989C>T p.D663= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs201923200, COSV64004036; called by muse, mutect2, varscan2
- GRK4 | c.1017A>G p.E339= (on ENST00000398052 / NM_182982.3; = p.E307= on NM_005307.3) | Silent (SNP) | VAF 47/65 reads (72%) | catalogued as rs370820505; called by muse, mutect2, varscan2
- HEATR6 | c.3480G>A p.E1160= | Silent (SNP) | VAF 8/137 reads (6%) | catalogued as COSV99482300; called by muse, mutect2
- HECW1 | c.4254G>A p.T1418= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs199970050, COSV101222625, COSV67827355; called by muse, mutect2, varscan2
- MTHFS | c.234C>T p.C78= | Silent (SNP) | VAF 383/471 reads (81%) | catalogued as rs755737435, COSV51915861; called by muse, mutect2, varscan2
- NUP93 | c.156C>T p.S52= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV57434520; called by muse, mutect2, varscan2
- RIN2 | c.1983G>A p.K661= (on ENST00000255006 / NM_001242581.1; = p.K612= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV54795020; called by muse, mutect2, varscan2
- SUGP2 | c.2481C>T p.F827= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV58266154; called by muse, mutect2, varscan2
- SYNDIG1L | c.585C>T p.D195= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV59048652; called by muse, mutect2, varscan2
- TNXB | c.8076C>T p.Y2692= (on ENST00000647633; = p.Y2445= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV64489872; called by muse, mutect2, varscan2
- TRAM1L1 | c.855T>C p.D285= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as COSV60293547; called by muse, mutect2, varscan2
- ADARB2 | c.101-147665C>G | Intron (SNP) | VAF 31/126 reads (25%) | catalogued as COSV101184502; called by muse, mutect2, varscan2
- OBSCN | c.11660-1168G>C | Intron (SNP) | VAF 36/110 reads (33%) | catalogued as COSV52836182; called by muse, mutect2, varscan2
